Somatic mutation profile of tumor specimen TCGA-SI-A71O-06A (aliquot TCGA-SI-A71O-06A-11D-A387-09) from TCGA case TCGA-SI-A71O, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant peripheral nerve sheath tumor; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 29.3 years (10,710 days).
Specimen TCGA-SI-A71O-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2909eac4-7bea-44c7-b2d1-988db3f1c142.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-SI-A71O-10A (Blood Derived Normal), aliquot TCGA-SI-A71O-10A-01D-A33H-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/580decc4-f025-42b6-8b3e-6d58dc40f1c3

The open-access MAF lists 40 somatic variants for this specimen: 28 protein-altering or splice-affecting, 10 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 23, Silent 10, Nonsense Mutation 2, 3'Flank 1, Frame Shift Ins 1, In Frame Del 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APBB2 | c.2248C>T p.Q750* (on ENST00000295974 / NM_001166050.2; = p.Q751* on NM_004307.2) | Nonsense Mutation (SNP) | VAF 10/57 reads (18%) | catalogued as COSV99922490; called by muse, mutect2, varscan2
- ARHGAP6 | c.1684C>G p.L562V | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.954); catalogued as COSV100272320; called by muse, mutect2
- CACNA1E | c.271T>A p.F91I | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100701300; called by muse, mutect2, varscan2
- EHD1 | c.605A>G p.E202G | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100276859; called by muse, mutect2, varscan2
- GADL1 | c.897T>G p.H299Q | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99243811; called by muse, mutect2, varscan2
- GOLGA8G | c.1383G>C p.Q461H | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.272); catalogued as COSV100284580; called by muse, mutect2, varscan2
- GRIA3 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 10/31 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV99989071; called by muse, varscan2
- INPP4A | c.2431G>A p.E811K (on ENST00000074304 / NM_001134224.1; = p.E772K on NM_001566.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50785493, COSV99302666; called by muse, mutect2, varscan2
- INVS | c.2818C>T p.R940W | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as rs116654016, COSV52452350; called by muse, mutect2, varscan2
- MIDEAS | c.73C>G p.P25A | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV99678617; called by muse, mutect2, varscan2
- MUC16 | c.1136C>T p.T379I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.006); catalogued as COSV101198291; called by muse, mutect2, varscan2
- OR10G9 | c.137T>C p.V46A | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.85); PolyPhen benign (0.021); catalogued as COSV100901480; called by muse, mutect2, varscan2
- PAPPA2 | c.3684C>A p.N1228K | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV100867603; called by muse, mutect2, varscan2
- PAX5 | c.293A>T p.K98I | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV100814049; called by muse, mutect2, varscan2
- RHO | c.47C>T p.A16V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs201340914, COSV56213268; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC15A1 | c.851T>C p.M284T | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.574); catalogued as COSV100919425; called by muse, mutect2, varscan2
- SNX3 | c.404C>G p.A135G | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100017929; called by mutect2, varscan2
- TRPV5 | c.1676A>C p.N559T | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV99520128; called by muse, mutect2, varscan2
- UGT2B10 | c.669C>A p.F223L | Missense Mutation (SNP) | VAF 15/80 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV55318314, COSV99607898; called by muse, mutect2, varscan2
- UGT2B10 | c.670C>A p.Q224K | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.035); catalogued as COSV99607903; called by muse, mutect2, varscan2
- VSIG10 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.058); catalogued as rs377153797, COSV63654519; called by muse, mutect2, varscan2
- VWA3A | c.1286C>A p.P429H | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100240646; called by muse, mutect2, varscan2
- ZFP28 | c.1564C>T p.Q522* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | catalogued as COSV100019282; called by muse, mutect2, varscan2
- ZNF81 | c.1643A>C p.H548P | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100095396; called by muse, mutect2, varscan2
- IGLV3-25 | c.101G>T p.G34V | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- NOC4L | c.229del p.V77Sfs*2 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, varscan2
- POLR3B | c.265_267del p.E89del | In Frame Del (DEL) | VAF 9/57 reads (16%) | called by pindel, varscan2
- PRKDC | c.4092dup p.N1365* | Frame Shift Ins (INS) | VAF 7/22 reads (32%) | called by mutect2, varscan2
- ABCA13 | c.1041C>T p.S347= | Silent (SNP) | VAF 4/68 reads (6%) | catalogued as COSV101329934; called by muse, mutect2
- ATP1A3 | c.567G>A p.V189= (on ENST00000545399 / NM_001256214.2; = p.V176= on NM_152296.5) | Silent (SNP) | VAF 6/22 reads (27%) | catalogued as COSV100131984; called by muse, varscan2
- LARGE2 | c.1290C>T p.H430= | Silent (SNP) | VAF 8/22 reads (36%) | catalogued as rs766190878, COSV99138078; called by muse, mutect2, varscan2
- LORICRIN | c.840C>T p.G280= | Silent (SNP) | VAF 8/18 reads (44%) | catalogued as COSV100907272, COSV64201271; called by mutect2, varscan2
- OPN1LW | c.159C>T p.Y53= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as COSV100886854; called by muse, mutect2, varscan2
- PCDHA1 | c.2025G>A p.A675= | Silent (SNP) | VAF 8/52 reads (15%) | catalogued as rs143057294; called by muse, mutect2, varscan2
- SEC14L2 | c.993G>A p.G331= | Silent (SNP) | VAF 3/38 reads (8%) | called by muse, mutect2
- SPIC | c.135T>G p.P45= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as COSV100162852; called by muse, varscan2
- SPPL2C | c.228C>A p.P76= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV100233944; called by muse, mutect2, varscan2
- ZFP28 | c.2385C>T p.I795= | Silent (SNP) | VAF 16/64 reads (25%) | catalogued as COSV100019285; called by muse, mutect2, varscan2
- DEFB119 | c.61+1299A>T | Intron (SNP) | VAF 29/107 reads (27%) | catalogued as COSV100190572; called by muse, mutect2, varscan2
- MYL3 | chr3:46830419 G>A | 3'Flank (SNP) | VAF 4/33 reads (12%) | catalogued as rs771857315, COSV101451245; called by mutect2, varscan2
